Somatic mutation profile of tumor specimen MP2PRT-PAURZG-TMP1-A (aliquot MP2PRT-PAURZG-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAURZG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,685 days).
Specimen MP2PRT-PAURZG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4750de8-5776-49ef-8d03-cc038b52f6e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAURZG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAURZG-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/111886c1-3691-4dea-ba73-51c421cf2c07

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 13, Silent 9, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.682+1G>A p.X228_splice | Splice Site (SNP) | VAF 51/252 reads (20%) | catalogued as rs775288140, CS072163, CS971697, COSV100096307; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IGHV1-46 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1337425972; called by muse, varscan2
- PCDHB12 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.107); catalogued as rs371515374, COSV53398083; called by muse, mutect2, varscan2
- PTPRS | c.4801G>A p.V1601I | Missense Mutation (SNP) | VAF 149/355 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs367918810; called by muse, mutect2, varscan2
- RPL10L | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 214/427 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs779859790; called by muse, mutect2, varscan2
- SLC6A17 | c.1957G>A p.V653M | Missense Mutation (SNP) | VAF 87/363 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs757150136; called by muse, mutect2, varscan2
- TAF4 | c.3167C>T p.T1056M | Missense Mutation (SNP) | VAF 15/550 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575922992, COSV53343889; called by muse, mutect2
- VRTN | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 66/519 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200392703; called by muse, mutect2, varscan2
- ARFGEF2 | c.3505C>T p.L1169F | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CRHR1 | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 269/544 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECT2 | c.2251C>T p.H751Y (on ENST00000392692 / NM_001349098.2; = p.H720Y on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.209); called by muse, mutect2
- KCNV1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC16 | c.3750C>A p.S1250R | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- REST | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 25/342 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BOC | c.2097C>T p.Y699= | Silent (SNP) | VAF 137/561 reads (24%) | catalogued as rs987544617; called by muse, mutect2, varscan2
- DNAH5 | c.2940C>T p.A980= | Silent (SNP) | VAF 26/264 reads (10%) | called by muse, mutect2, varscan2
- IGHV3-53 | c.350delinsTTGAC p.*117delinsVD | Silent (INS) | VAF 87/97 reads (90%) | called by pindel, varscan2*
- IGKV1OR2-108 | chr2:113406872 TCACAGTGTTACAAGCCATAA>AAGGGC | Silent (DEL) | VAF 58/156 reads (37%) | called by pindel, varscan2*
- ITPRID1 | c.2196A>T p.G732= | Silent (SNP) | VAF 170/374 reads (45%) | called by muse, mutect2, varscan2
- OR4X1 | c.753T>A p.P251= | Silent (SNP) | VAF 124/322 reads (39%) | called by muse, mutect2
- SLC2A5 | c.795G>T p.V265= | Silent (SNP) | VAF 230/490 reads (47%) | called by muse, mutect2, varscan2
- SPRED1 | c.123C>T p.S41= | Silent (SNP) | VAF 27/531 reads (5%) | catalogued as rs748759533, COSV54436511; called by muse, mutect2
- ZSWIM8 | c.972G>A p.T324= | Silent (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
